Somatic mutation profile of tumor specimen C3L-07963-01 (aliquot CPT0452850006) from CPTAC case C3L-07963, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.7 years (24,372 days).
Specimen C3L-07963-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89a66947-9fbf-4e3b-8af7-beff00ccb162.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07963-31 (Blood Derived Normal), aliquot CPT0453000003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e6df602-1c92-42b2-a406-c2bc0dc02c49

The open-access MAF lists 182 somatic variants for this specimen: 132 protein-altering or splice-affecting, 44 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 44, Nonsense Mutation 7, Frame Shift Ins 2, 5'Flank 2, Frame Shift Del 2, Intron 2, Splice Region 1, 5'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC104452.1 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as CM983428; called by muse, mutect2, varscan2
- ACR | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 78/377 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576896841, COSV53360582; called by muse, mutect2, varscan2
- ACTL6B | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 403/657 reads (61%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs773244976, COSV50517728; called by muse, mutect2, varscan2
- ACTL9 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.218); catalogued as rs1568430953, COSV61004535; called by muse, mutect2, varscan2
- ADARB2 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 97/494 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs763599291; called by muse, mutect2, varscan2
- ADCY1 | c.1328C>T p.T443M | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs376984015; called by muse, mutect2, varscan2
- ADRA1B | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 89/402 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.568); catalogued as COSV60701795; called by muse, mutect2, varscan2
- AGRN | c.4498G>A p.E1500K | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs200870228, COSV65070279; called by muse, mutect2, varscan2
- ANKS1A | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 30/554 reads (5%) | catalogued as COSV100832969; called by muse, mutect2
- ASPSCR1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 96/449 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs368957042; called by muse, mutect2, varscan2
- ATP5MC3 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 33/381 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs760457976; called by muse, mutect2
- ATR | c.2986C>T p.Q996* | Nonsense Mutation (SNP) | VAF 40/260 reads (15%) | catalogued as COSV63384932; called by muse, mutect2, varscan2
- ATXN7L3 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 43/532 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231725; called by muse, mutect2
- BOD1L1 | c.8657C>T p.T2886M | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs761727087; called by muse, mutect2
- CACNA2D2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1456109864; called by muse, mutect2, varscan2
- CELSR1 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 51/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763662565; called by muse, mutect2
- CSMD1 | c.7910C>T p.T2637M (on ENST00000520002; = p.T2636M on NM_033225.6) | Missense Mutation (SNP) | VAF 46/361 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1184531132, COSV59292521; called by muse, mutect2, varscan2
- CSPG4 | c.3178C>T p.R1060C | Missense Mutation (SNP) | VAF 66/388 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542356318; called by muse, mutect2, varscan2
- CYP4F8 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 72/351 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs879518280, COSV100358274; called by muse, mutect2
- DLL1 | c.1960G>A p.V654I | Missense Mutation (SNP) | VAF 111/561 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs775884511, COSV64537656; called by muse, mutect2, varscan2
- DNAI4 | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV64021493; called by muse, mutect2
- ELAPOR1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs138658561; called by muse, mutect2
- ERBB4 | c.3640A>T p.N1214Y | Missense Mutation (SNP) | VAF 68/420 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV61467171; called by muse, mutect2, varscan2
- EYS | c.216A>C p.Q72H | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV60981412; called by muse, mutect2
- EZH2 | c.1225G>A p.E409K (on ENST00000460911 / NM_001203247.2; = p.E414K on NM_004456.5) | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); catalogued as COSV100237286; called by muse, mutect2, varscan2
- FARP1 | c.2432C>T p.T811M | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs192616500; called by muse, mutect2
- GALNT18 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 40/433 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs764285689; called by muse, mutect2
- GLI2 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 75/434 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs1419274436, COSV100082645; called by muse, mutect2, varscan2
- GNAS | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 72/502 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs570213695, COSV58327309; called by muse, mutect2, varscan2
- GRAMD1B | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs748832223, COSV59207710; called by muse, mutect2, varscan2
- HIRA | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 15/303 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451572445; called by muse, mutect2
- HOXB1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.883); catalogued as rs376245728; called by muse, mutect2
- ITGA4 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs762837438; called by muse, mutect2
- KCNT1 | c.2047G>A p.G683S (on ENST00000488444; = p.G702S on NM_020822.3) | Missense Mutation (SNP) | VAF 120/527 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs550447485, COSV53711032; ClinVar: likely benign; called by muse, mutect2, varscan2
- MASP1 | c.2070G>A p.W690* | Nonsense Mutation (SNP) | VAF 28/258 reads (11%) | catalogued as rs770475640, COSV100537201; called by muse, mutect2, varscan2
- MATN4 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 89/460 reads (19%) | PolyPhen possibly damaging (0.532); catalogued as rs918268552, COSV59212726; called by muse, mutect2, varscan2
- MXRA7 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 41/421 reads (10%) | PolyPhen probably damaging (0.946); catalogued as rs1051464067; called by muse, mutect2
- NMNAT2 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 57/326 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1188292900, COSV54267602; called by muse, mutect2, varscan2
- NPTX2 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 49/941 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs201822467; called by muse, mutect2
- PCDHGA4 | c.1535G>A p.S512N | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99532040, COSV99534996; called by muse, mutect2, varscan2
- PLCH2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 63/346 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as rs559294543; called by muse, mutect2, varscan2
- PLEKHO2 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 60/495 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs370016813; called by muse, mutect2, varscan2
- POLRMT | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs201346718; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs530097531; called by muse, mutect2, varscan2
- PRICKLE2 | c.2278G>A p.E760K (on ENST00000295902; = p.E704K on NM_198859.4) | Missense Mutation (SNP) | VAF 260/625 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as rs959568626, COSV55766742; called by muse, mutect2, varscan2
- RGPD3 | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 72/676 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs567422835; called by muse, varscan2
- RYR1 | c.5860C>T p.R1954C | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1354061498; ClinVar: uncertain significance; called by muse, mutect2
- RYR3 | c.10855C>T p.R3619W (on ENST00000389232; = p.R3620W on NM_001036.6) | Missense Mutation (SNP) | VAF 20/445 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477239834, COSV101214630; called by muse, mutect2
- S100A16 | c.153G>A p.S51= | Splice Region (SNP) | VAF 35/263 reads (13%) | catalogued as rs753774747; called by muse, mutect2, varscan2
- SCN8A | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 56/562 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.327); catalogued as rs775833241; called by muse, mutect2
- SCUBE1 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1289551558, COSV62615288; called by muse, mutect2
- SDK1 | c.1822G>A p.V608I | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as rs759494831; called by muse, mutect2, varscan2
- SDK1 | c.3898G>A p.V1300M | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs751445473, COSV67356887; called by muse, mutect2, varscan2
- SHPRH | c.3317A>C p.Y1106S (on ENST00000275233 / NM_001042683.3; = p.Y1115S on NM_173082.3) | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99262652; called by muse, mutect2
- SIGLEC7 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs140841032, COSV58317452; called by muse, mutect2, varscan2
- SLC7A14 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 29/516 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs202048294, COSV51581905; ClinVar: uncertain significance; called by muse, mutect2
- SOGA1 | c.3059G>A p.R1020Q | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.526); catalogued as rs201255724; called by muse, mutect2, varscan2
- SORCS1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs575431793, COSV53854383; called by muse, mutect2, varscan2
- SORCS1 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 69/461 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99547324; called by muse, mutect2, varscan2
- STK32B | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1202515538; called by muse, mutect2
- TBATA | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 68/445 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs768147593, COSV54720809; called by muse, mutect2, varscan2
- TRHDE | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 98/534 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs766599290, COSV53847095; called by muse, mutect2, varscan2
- TSPOAP1 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 59/281 reads (21%) | catalogued as rs754987164, COSV52111775; called by muse, mutect2, varscan2
- TTN | c.55886G>T p.S18629I (on ENST00000591111; = p.S11205I on NM_003319.4) | Missense Mutation (SNP) | VAF 62/394 reads (16%) | PolyPhen benign (0.014); catalogued as COSV60293428; called by muse, mutect2, varscan2
- WDR25 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 70/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771944170; called by muse, mutect2, varscan2
- ZFHX3 | c.2551G>A p.G851S | Missense Mutation (SNP) | VAF 42/417 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.069); catalogued as rs1356895082, COSV99214526; called by muse, mutect2, varscan2
- ZIC3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs772291510; called by muse, varscan2
- ZNF469 | c.10897C>G p.P3633A (on ENST00000437464; = p.P3661A on NM_001367624.2) | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1050476269, COSV71258394; called by muse, mutect2
- ZNF536 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 71/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835381, COSV62827327; called by muse, mutect2, varscan2
- ZNF609 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 59/356 reads (17%) | catalogued as COSV58582137; called by muse, mutect2, varscan2
- ACAD10 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 138/428 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ADGRL1 | c.3568G>T p.V1190L (on ENST00000340736 / NM_001008701.3; = p.V1185L on NM_014921.5) | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2
- AL354761.1 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.058); called by muse, mutect2
- ANAPC10 | c.550A>C p.I184L | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.122); called by muse, mutect2
- ANKRD12 | c.5813G>A p.R1938K | Missense Mutation (SNP) | VAF 41/418 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2
- ANKRD31 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL2 | c.2089G>A p.G697S | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP8B2 | c.3020G>A p.G1007E (on ENST00000672630; = p.G974E on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/395 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- C6orf132 | c.3550C>T p.R1184W | Missense Mutation (SNP) | VAF 53/593 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); called by muse, mutect2
- CCDC168 | c.3346del p.M1116Wfs*8 | Frame Shift Del (DEL) | VAF 21/188 reads (11%) | called by mutect2, pindel, varscan2
- CDH12 | c.2323T>C p.F775L | Missense Mutation (SNP) | VAF 74/391 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CMYA5 | c.9815C>T p.S3272L | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2
- CSMD1 | c.1017A>C p.Q339H | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- DLGAP4 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPEP2NB | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDC3 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 57/419 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EPHA5 | c.2951A>G p.E984G | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- FAM20B | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBXO15 | c.1417G>T p.G473* | Nonsense Mutation (SNP) | VAF 120/468 reads (26%) | called by muse, mutect2, varscan2
- FOXE3 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FSIP2 | c.4040G>A p.S1347N | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRK7 | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 27/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- IGHM | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 73/460 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- IQCN | c.3430C>T p.Q1144* | Nonsense Mutation (SNP) | VAF 57/400 reads (14%) | called by muse, mutect2, varscan2
- KCNC1 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 84/422 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDM6B | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 96/516 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KLHL30 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.158); called by muse, mutect2
- KMT2B | c.7363T>C p.S2455P | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRP1B | c.6622T>A p.L2208I | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2
- LRTM1 | c.434G>C p.W145S | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.388); called by muse, mutect2
- MAPK8IP1 | c.47del p.P16Rfs*81 | Frame Shift Del (DEL) | VAF 60/356 reads (17%) | called by mutect2, pindel, varscan2
- MED12 | c.2800C>T p.H934Y | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MEIOC | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, varscan2
- MLKL | c.1013T>C p.L338P | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MORC1 | c.2129T>A p.V710E | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- NALCN | c.4639A>T p.S1547C | Missense Mutation (SNP) | VAF 118/321 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- NDST3 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NOL11 | c.1378A>T p.I460F | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NPC1L1 | c.3131T>C p.V1044A | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2
- PCDHA5 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 57/565 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.304); called by muse, mutect2
- PCDHGA6 | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PDE1B | c.364T>G p.F122V | Missense Mutation (SNP) | VAF 39/545 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDE3A | c.860A>C p.K287T | Missense Mutation (SNP) | VAF 234/1061 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- POTEI | c.2433C>G p.N811K | Missense Mutation (SNP) | VAF 83/550 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRAMEF2 | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- PRKDC | c.3203T>C p.L1068P | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PROKR1 | c.917_918dup p.R307Cfs*10 | Frame Shift Ins (INS) | VAF 61/456 reads (13%) | called by mutect2, pindel, varscan2
- PTGER1 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 31/473 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2
- SLX4IP | c.955G>C p.V319L | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- SREK1IP1 | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- TENM1 | c.1778A>G p.E593G | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TEX13C | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.638); called by muse, mutect2
- TP53 | c.680_712del p.S227_M237del | In Frame Del (DEL) | VAF 30/280 reads (11%) | called by mutect2, pindel
- TRHDE | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 75/353 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TRIR | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); called by muse, mutect2
- TTN | c.9278A>G p.D3093G (on ENST00000591111; = p.D3047G on NM_003319.4) | Missense Mutation (SNP) | VAF 70/396 reads (18%) | PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TTN | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 49/355 reads (14%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUB | c.155C>A p.A52E (on ENST00000299506 / NM_177972.3; = p.A107E on NM_003320.4) | Missense Mutation (SNP) | VAF 42/588 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- UBE3A | c.1121G>A p.C374Y | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- USP34 | c.6568G>A p.E2190K | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- VIPR2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- ZNF112 | c.1265dup p.S423Efs*5 (on ENST00000337401 / NM_001083335.2; = p.S417Efs*5 on NM_013380.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 30/266 reads (11%) | called by mutect2, pindel, varscan2
- ANKRD30B | c.3792A>G p.A1264= | Silent (SNP) | VAF 69/246 reads (28%) | called by muse, mutect2, varscan2
- C8orf34 | c.708G>C p.L236= | Silent (SNP) | VAF 49/301 reads (16%) | called by muse, mutect2, varscan2
- CIAO3 | c.456C>T p.F152= | Silent (SNP) | VAF 32/295 reads (11%) | catalogued as rs560599074, COSV52402738, COSV99284926; called by muse, mutect2, varscan2
- CST9 | c.279C>T p.S93= | Silent (SNP) | VAF 35/275 reads (13%) | called by muse, mutect2, varscan2
- ETV3L | c.42C>T p.P14= | Silent (SNP) | VAF 43/469 reads (9%) | catalogued as rs148267509; called by muse, mutect2
- FBLL1 | c.45C>T p.R15= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- FBN1 | c.5247A>G p.G1749= | Silent (SNP) | VAF 43/309 reads (14%) | called by muse, mutect2, varscan2
- FLG | c.6684A>G p.G2228= | Silent (SNP) | VAF 33/378 reads (9%) | called by muse, mutect2
- GAREM2 | c.1098G>A p.A366= | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- GOLGA6L7 | c.438C>T p.S146= | Silent (SNP) | VAF 40/235 reads (17%) | catalogued as rs766415024; called by muse, mutect2, varscan2
- HEY2 | c.498G>A p.A166= | Silent (SNP) | VAF 17/465 reads (4%) | catalogued as COSV64239819; called by muse, mutect2
- HKDC1 | c.1146G>A p.S382= | Silent (SNP) | VAF 101/490 reads (21%) | catalogued as rs780344073, COSV63576117; called by muse, mutect2, varscan2
- HSPA12B | c.90G>A p.P30= | Silent (SNP) | VAF 64/371 reads (17%) | catalogued as rs373465808; called by muse, mutect2, varscan2
- KCND2 | c.1032C>T p.Y344= | Silent (SNP) | VAF 28/301 reads (9%) | catalogued as rs1490973208, COSV58568917, COSV58575538; called by muse, mutect2
- KCNK13 | c.390C>T p.Y130= | Silent (SNP) | VAF 63/446 reads (14%) | catalogued as rs755523519, COSV56413675; called by muse, mutect2, varscan2
- KCNK16 | c.408C>T p.N136= | Silent (SNP) | VAF 54/478 reads (11%) | catalogued as rs562223126, COSV64678306; called by muse, mutect2, varscan2
- MDFIC | c.15C>A p.G5= | Silent (SNP) | VAF 24/271 reads (9%) | catalogued as rs754402968; called by muse, mutect2
- MEGF6 | c.3186G>A p.A1062= | Silent (SNP) | VAF 59/360 reads (16%) | catalogued as rs370693971, COSV53888381; called by muse, mutect2, varscan2
- MFSD4A | c.525G>A p.T175= | Silent (SNP) | VAF 140/519 reads (27%) | catalogued as rs757538864; called by muse, mutect2, varscan2
- MRC1 | c.1908G>A p.P636= | Silent (SNP) | VAF 93/528 reads (18%) | catalogued as rs781948465; called by muse, mutect2, varscan2
- MSI2 | c.75C>A p.I25= | Silent (SNP) | VAF 18/172 reads (10%) | called by mutect2, varscan2
- MXRA5 | c.6927C>A p.L2309= | Silent (SNP) | VAF 109/295 reads (37%) | called by muse, mutect2, varscan2
- NECAP1 | c.561C>T p.L187= | Silent (SNP) | VAF 18/476 reads (4%) | catalogued as COSV60250829; called by muse, mutect2
- NIPBL | c.687C>T p.G229= | Silent (SNP) | VAF 33/417 reads (8%) | called by muse, mutect2
- NLRP14 | c.1722A>G p.P574= | Silent (SNP) | VAF 29/292 reads (10%) | catalogued as rs565320024; called by muse, mutect2, varscan2
- OBSCN | c.13104G>A p.V4368= | Silent (SNP) | VAF 49/636 reads (8%) | called by muse, mutect2
- OR10X1 | c.666T>G p.G222= | Silent (SNP) | VAF 48/290 reads (17%) | catalogued as COSV100936714; called by muse, mutect2, varscan2
- OR2Y1 | c.510C>T p.G170= | Silent (SNP) | VAF 38/438 reads (9%) | called by muse, mutect2
- PCDHA12 | c.2160G>A p.A720= | Silent (SNP) | VAF 43/321 reads (13%) | catalogued as COSV56482570; called by muse, mutect2, varscan2
- PCDHA3 | c.1347C>T p.N449= | Silent (SNP) | VAF 48/546 reads (9%) | catalogued as rs374473436, COSV63545410; called by muse, mutect2
- PLCXD1 | c.36G>A p.S12= | Silent (SNP) | VAF 62/362 reads (17%) | catalogued as rs201477118; called by muse, mutect2, varscan2
- PRSS53 | c.981C>T p.G327= | Silent (SNP) | VAF 40/528 reads (8%) | catalogued as rs371720280, COSV99762197; called by muse, mutect2
- PXDN | c.1785G>A p.V595= | Silent (SNP) | VAF 66/414 reads (16%) | catalogued as COSV99414994; called by muse, mutect2, varscan2
- RBFOX1 | c.873G>A p.P291= | Silent (SNP) | VAF 41/306 reads (13%) | catalogued as rs761510301; ClinVar: likely benign; called by muse, mutect2, varscan2
- RIMS1 | c.1182G>A p.A394= | Silent (SNP) | VAF 30/292 reads (10%) | called by muse, mutect2, varscan2
- RTL1 | c.111G>T p.S37= | Silent (SNP) | VAF 65/430 reads (15%) | catalogued as rs776009747; called by mutect2, varscan2
- SLC22A18 | c.492C>G p.V164= | Silent (SNP) | VAF 39/333 reads (12%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.1101C>T p.Y367= | Silent (SNP) | VAF 340/571 reads (60%) | catalogued as rs777458586, COSV53932022; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SOX3 | c.1314C>T p.N438= | Silent (SNP) | VAF 77/189 reads (41%) | catalogued as COSV65167852; called by muse, mutect2, varscan2
- STOX2 | c.2649C>T p.P883= | Silent (SNP) | VAF 39/367 reads (11%) | catalogued as rs555913757, COSV100408991; called by muse, mutect2, varscan2
- UBE2QL1 | c.252C>T p.G84= | Silent (SNP) | VAF 74/453 reads (16%) | catalogued as rs1241932038, COSV67715418; called by muse, mutect2, varscan2
- UTF1 | c.714G>A p.A238= | Silent (SNP) | VAF 48/248 reads (19%) | called by muse, mutect2, varscan2
- ZNF175 | c.507A>C p.T169= | Silent (SNP) | VAF 16/359 reads (4%) | called by muse, mutect2
- ZNF451 | c.2644C>T p.L882= | Silent (SNP) | VAF 27/368 reads (7%) | catalogued as rs771929745; called by muse, mutect2
- AC093512.2 | c.306+3639G>A | Intron (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
- ARHGEF4 | chr2:130916456 C>T | 5'Flank (SNP) | VAF 83/428 reads (19%) | called by muse, mutect2, varscan2
- BORA | c.-101G>A | 5'UTR (SNP) | VAF 124/481 reads (26%) | catalogued as rs764919474; called by muse, mutect2, varscan2
- POLR1B | chr2:112542416 G>C | 5'Flank (SNP) | VAF 44/372 reads (12%) | catalogued as rs769542609, COSV99271059; called by muse, varscan2
- XIST | n.9737C>T | RNA (SNP) | VAF 58/190 reads (31%) | catalogued as rs1369299543; called by muse, mutect2, varscan2
- ZNF829 | c.-85+132G>A | Intron (SNP) | VAF 48/527 reads (9%) | catalogued as rs1160034720; called by muse, mutect2
